Somatic mutation profile of tumor specimen 0DDZ6M from CCDI case PBBPJU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,492 days).
Specimen 0DDZ6M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2c01047-5de0-41f0-9c80-8af4f6d26b9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDZ62 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/572c052b-0f6e-4c87-a3bb-d59b7fe5d152

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 4, Silent 3, Intron 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 179/272 reads (66%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADSB | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1266747835, COSV62550543; called by muse, mutect2, varscan2
- SORL1 | c.3284G>A p.W1095* | Nonsense Mutation (SNP) | VAF 14/366 reads (4%) | catalogued as COSV52757310; called by muse, mutect2
- TNXB | c.6565G>A p.D2189N (on ENST00000647633; = p.D1942N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/493 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs765461982; called by muse, mutect2, varscan2
- DOT1L | c.1343C>A p.S448* | Nonsense Mutation (SNP) | VAF 61/327 reads (19%) | called by muse, mutect2, varscan2
- FAXDC2 | c.245-5C>A | Splice Region (SNP) | VAF 63/348 reads (18%) | called by muse, mutect2, varscan2
- INTS2 | c.2976A>T p.E992D | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- MRPS5 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 79/282 reads (28%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.482T>C p.F161S | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUBB | c.1257_1264del p.E421Afs*15 | Frame Shift Del (DEL) | VAF 234/493 reads (47%) | called by mutect2, pindel, varscan2
- USF3 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 225/407 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- WDFY1 | c.422T>C p.M141T | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2
- FICD | c.1107C>T p.N369= | Silent (SNP) | VAF 89/419 reads (21%) | catalogued as rs536678902, COSV57206550; called by muse, mutect2, varscan2
- SLC9A8 | c.1707C>A p.G569= | Silent (SNP) | VAF 107/360 reads (30%) | called by muse, mutect2, varscan2
- TMEM120B | c.510C>T p.T170= | Silent (SNP) | VAF 70/373 reads (19%) | called by muse, mutect2, varscan2
- BRF1 | c.544+3202C>T | Intron (SNP) | VAF 104/252 reads (41%) | called by muse, mutect2, varscan2
- CLUH | c.2490+29A>G | Intron (SNP) | VAF 146/508 reads (29%) | catalogued as rs759949300; called by muse, mutect2, varscan2
